Somatic mutation profile of tumor specimen 0DCFVW from CCDI case PBBMFA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 15.1 years (5,498 days).
Specimen 0DCFVW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c92200b-d066-4511-ac3b-3c35c862d4ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCFVQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/955e34c6-312d-4422-8a92-dc110142125d

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, 3'UTR 1, Frame Shift Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL23A1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 42/423 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as rs1385600191; called by muse, mutect2, varscan2
- GRM1 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 56/756 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51116944, COSV51170387; called by muse, mutect2
- IKZF4 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 70/692 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs367879107; called by muse, mutect2, varscan2
- MED13L | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 69/635 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- RBM5 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 43/763 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- SETD2 | c.4623_4639del p.N1541Kfs*41 | Frame Shift Del (DEL) | VAF 56/610 reads (9%) | called by mutect2, pindel
- IRX6 | c.606G>A p.R202= | Silent (SNP) | VAF 132/1574 reads (8%) | called by muse, mutect2
- ITGAM | c.2181G>A p.V727= (on ENST00000648685 / NM_001145808.2; = p.V726= on NM_000632.4) | Silent (SNP) | VAF 76/712 reads (11%) | called by muse, mutect2, varscan2
- MMP7 | c.174A>G p.K58= | Silent (SNP) | VAF 44/778 reads (6%) | called by muse, mutect2
- PNLIPRP2 | c.1002G>A p.K334= | Silent (SNP) | VAF 23/752 reads (3%) | catalogued as rs782260443; called by muse, mutect2
- AADACL4 | c.*22G>A | 3'UTR (SNP) | VAF 34/310 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.5683C>T | RNA (SNP) | VAF 26/596 reads (4%) | called by muse, mutect2
- SPINK4 | c.216-39C>T | Intron (SNP) | VAF 13/419 reads (3%) | called by muse, mutect2
